Somatic mutation profile of tumor specimen TARGET-20-PASLDL-09A (aliquot TARGET-20-PASLDL-09A-02D) from TARGET case TARGET-20-PASLDL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.1 years (2,964 days).
Specimen TARGET-20-PASLDL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f7013c4-1d43-4ab0-b022-88d20a5e398c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASLDL-14A (Bone Marrow Normal), aliquot TARGET-20-PASLDL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5105086-e761-4e08-b483-27f55b95ae87

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 3'UTR 4, Intron 1, 5'UTR 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 34/121 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 20/174 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic; called by mutect2, varscan2
- CCDC168 | c.16901T>C p.V5634A | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.555); catalogued as rs370800336; called by muse, mutect2, varscan2
- EP300 | c.3431A>G p.K1144R | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1422775274; called by muse, mutect2, varscan2
- HDAC4 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455660198; called by muse, mutect2, varscan2
- MYCBP2 | c.2973T>A p.D991E (on ENST00000357337; = p.D1029E on NM_015057.5) | Missense Mutation (SNP) | VAF 72/147 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs771196712; called by muse, mutect2, varscan2
- PRUNE2 | c.3211G>A p.V1071I | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs192767331, COSV104428527; called by muse, mutect2, varscan2
- SPEG | c.7876T>C p.S2626P | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs200008141; called by muse, mutect2, varscan2
- ARID1B | c.4855+2_4855+3insGCT p.X1619_splice | Splice Site (INS) | VAF 32/90 reads (36%) | called by mutect2, pindel, varscan2
- DNAH9 | c.7816C>A p.L2606I | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MACF1 | c.3331G>C p.V1111L | Missense Mutation (SNP) | VAF 58/140 reads (41%) | called by muse, mutect2, varscan2
- SIN3A | c.3396G>T p.R1132= | Silent (SNP) | VAF 66/138 reads (48%) | called by muse, mutect2, varscan2
- COL1A1 | c.*1309A>G | 3'UTR (SNP) | VAF 56/119 reads (47%) | catalogued as rs1201657090; called by muse, mutect2, varscan2
- DOCK8 | c.*177C>T | 3'UTR (SNP) | VAF 105/230 reads (46%) | catalogued as rs779550504; called by muse, mutect2, varscan2
- DPP6 | c.*988A>C | 3'UTR (SNP) | VAF 13/54 reads (24%) | catalogued as rs543370394, COSV59622748; called by muse, varscan2
- KIT | c.*367C>G | 3'UTR (SNP) | VAF 80/164 reads (49%) | catalogued as rs1009716803; called by muse, mutect2, varscan2
- PASK | c.3333+139G>T | Intron (SNP) | VAF 92/188 reads (49%) | catalogued as rs538088338, COSV99298790; called by muse, mutect2, varscan2
- RAD50 | c.-333C>T | 5'UTR (SNP) | VAF 12/20 reads (60%) | catalogued as rs753621196; called by muse, varscan2
